HCMI case HCM-BROD-0007-C49 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Myomatous Neoplasms; Primary site: Bronchus and lung. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/e506251d-4072-4479-b2ce-5c75387dc7fc

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: hispanic or latino; Year of birth: 2003; Vital status: Dead; Cause of death: Cancer Related.

Diagnoses (1)
1. Mixed type rhabdomyosarcoma: ICD-O-3 morphology code: 8902/3; ICD-10 code: C78.2; Tissue or organ of origin: Lung, NOS; Site of resection or biopsy: Pleura, NOS; Classification of tumor: metastasis; Age at diagnosis: 12.0 years (4,386 days); Metastasis at diagnosis: Metastasis, NOS; Prior malignancy: yes; Prior treatment: Yes; Cog rhabdomyosarcoma risk group: High Risk; Irs group: Group IV; Sites of involvement: Lung, NOS / Lymph node, NOS / Distant Nodes; Tumor confined to organ of origin: No.
   Pathology details: Tumor largest dimension diameter: 13 cm.
   Treatment given: Treatment type: Targeted Molecular Therapy; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 488 days (1.3 years); Days to treatment end: 519 days (1.4 years).
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide; Treatment intent type: Neoadjuvant; Regimen or line of therapy: VDC/IE.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Cyclophosphamide; Treatment intent type: Maintenance Therapy; Initial disease status: Progressive Disease; Regimen or line of therapy: VDC/IE; Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Doxorubicin; Treatment intent type: Neoadjuvant; Regimen or line of therapy: VDC/IE.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Doxorubicin; Treatment intent type: Maintenance Therapy; Initial disease status: Progressive Disease; Regimen or line of therapy: VDC/IE; Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Etoposide; Treatment intent type: Maintenance Therapy; Initial disease status: Progressive Disease; Regimen or line of therapy: VDC/IE; Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Etoposide; Treatment intent type: Neoadjuvant; Regimen or line of therapy: VDC/IE.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Ifosfamide; Treatment intent type: Maintenance Therapy; Initial disease status: Progressive Disease; Regimen or line of therapy: VDC/IE; Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Ifosfamide; Treatment intent type: Neoadjuvant; Regimen or line of therapy: VDC/IE.
   Treatment given: Treatment type: Targeted Molecular Therapy; Treatment intent type: Neoadjuvant.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Vincristine; Treatment intent type: Maintenance Therapy; Initial disease status: Progressive Disease; Regimen or line of therapy: VDC/IE; Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Vincristine; Treatment intent type: Neoadjuvant; Regimen or line of therapy: VDC/IE.
   Recorded as not given: adjuvant Chemotherapy, for residual disease; adjuvant Immunotherapy (Including Vaccines), for residual disease; neoadjuvant Radiation Therapy, NOS; adjuvant Radiation Therapy, NOS, for residual disease; Surgery, NOS, for initial diagnosis.

Follow-up (4 entries)
- Days to follow up: 0 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Lung, NOS; Days to progression: 0 days.
- Days to follow up: 0 days; Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Lymph node, NOS; Days to progression: 0 days.
- Days to follow up: 458 days (1.3 years); Progression or recurrence: Yes; Progression or recurrence anatomic site: Pleura, NOS; Days to progression: 458 days (1.3 years).
- Days to follow up: 519 days (1.4 years); Disease response: Stable Disease; Progression or recurrence: No.

Molecular and laboratory tests
- FOXO1 methylation: Equivocal.

Other clinical attributes
- Timepoint category: Initial Diagnosis; BMI: 27.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Family history
- Relative with cancer history: yes; Relationship type: First Degree Relative, NOS; Relationship primary diagnosis: Cancer.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample HCM-BROD-0007-C49-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
  Slide HCM-BROD-0007-C49-06A-01-S2-HE: Section location: Bottom; Percent tumor cells: 100; Percent tumor nuclei: 40; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide HCM-BROD-0007-C49-06A-01-S1-HE: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 70; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample HCM-BROD-0007-C49-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Whole Blood; Preservation method: Frozen.
- Sample HCM-BROD-0007-C49-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Mixed Adherent Suspension; Preservation method: Frozen; Passage count: 12.
